Somatic mutation profile of tumor specimen TCGA-G7-A8LB-01A (aliquot TCGA-G7-A8LB-01A-11D-A35Z-10) from TCGA case TCGA-G7-A8LB, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 70.6 years (25,782 days).
Specimen TCGA-G7-A8LB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 505f5492-c977-49ba-a018-b28dcd9edd6f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G7-A8LB-10A (Blood Derived Normal), aliquot TCGA-G7-A8LB-10A-01D-A35Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/71a312d6-e40c-463d-9411-9972127b59ec

The open-access MAF lists 102 somatic variants for this specimen: 87 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 67, Silent 14, Frame Shift Del 8, Frame Shift Ins 4, Nonsense Mutation 3, Splice Site 3, In Frame Del 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TTN | c.45373C>T p.R15125* (on ENST00000591111; = p.R7701* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 41/93 reads (44%) | catalogued as rs754866489, COSV59917424; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABHD18 | c.322C>G p.P108A | Missense Mutation (SNP) | VAF 75/159 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101180914; called by muse, mutect2, varscan2
- ADAM11 | c.2162C>T p.T721M | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); catalogued as rs149116155; called by muse, mutect2, varscan2
- ALDH1L1 | c.1759T>C p.C587R | Missense Mutation (SNP) | VAF 93/133 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99857665; called by muse, mutect2, varscan2
- ATXN7L2 | c.902G>A p.G301E | Missense Mutation (SNP) | VAF 39/71 reads (55%) | SIFT tolerated (0.98); PolyPhen benign (0.245); catalogued as COSV100881381; called by muse, mutect2, varscan2
- BCCIP | c.50C>T p.P17L | Missense Mutation (SNP) | VAF 37/70 reads (53%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs1394877405, COSV99533172; called by muse, mutect2, varscan2
- BICDL2 | c.700C>G p.L234V | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT tolerated (0.47); PolyPhen benign (0.048); catalogued as COSV99560854; called by muse, mutect2, varscan2
- CACNA1H | c.3443T>C p.L1148P | Missense Mutation (SNP) | VAF 265/772 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV100673678; called by muse, mutect2, varscan2
- CACNA2D3 | c.2612A>G p.Y871C | Missense Mutation (SNP) | VAF 64/85 reads (75%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.593); catalogued as COSV99878045; called by muse, mutect2, varscan2
- CAPN11 | c.479C>A p.P160H | Missense Mutation (SNP) | VAF 37/63 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101291980; called by muse, mutect2, varscan2
- CDH19 | c.285A>C p.R95S | Missense Mutation (SNP) | VAF 66/100 reads (66%) | SIFT tolerated (0.73); PolyPhen benign (0.053); catalogued as COSV100052552; called by muse, mutect2, varscan2
- CFHR2 | c.503A>G p.Y168C | Missense Mutation (SNP) | VAF 80/171 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100804408; called by muse, mutect2, varscan2
- CLEC4G | c.745C>T p.H249Y | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV100183741; called by muse, mutect2, varscan2
- CNOT6L | c.691T>C p.C231R (on ENST00000504123 / NM_001286790.2; = p.C226R on NM_144571.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.125); catalogued as COSV99362322; called by muse, mutect2, varscan2
- DHX8 | c.1301A>T p.D434V | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as COSV99292731; called by muse, mutect2, varscan2
- DIP2C | c.934G>A p.V312M | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.097); catalogued as rs762575049, COSV99794101; called by muse, mutect2, varscan2
- DYNC1I1 | c.1483G>T p.A495S | Missense Mutation (SNP) | VAF 82/131 reads (63%) | SIFT tolerated (0.15); PolyPhen benign (0.401); catalogued as COSV100269581; called by muse, mutect2, varscan2
- DYNC2I1 | c.140T>C p.M47T | Missense Mutation (SNP) | VAF 108/166 reads (65%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV101237863; called by muse, mutect2, varscan2
- EPG5 | c.1970A>G p.H657R | Missense Mutation (SNP) | VAF 50/129 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99958318; called by muse, mutect2, varscan2
- GTPBP8 | c.19C>T p.R7W | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as COSV99868570; called by muse, mutect2, varscan2
- GTSE1 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 66/113 reads (58%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.559); catalogued as COSV101483265; called by muse, mutect2, varscan2
- HECTD4 | c.10861G>A p.D3621N | Missense Mutation (SNP) | VAF 51/128 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.506); catalogued as rs958590083, COSV101108428; called by muse, mutect2, varscan2
- HERC4 | c.386+1G>A p.X129_splice | Splice Site (SNP) | VAF 39/73 reads (53%) | catalogued as COSV99517653; called by muse, mutect2, varscan2
- HMGCR | c.535A>G p.I179V | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as COSV99843525; called by muse, mutect2, varscan2
- INMT | c.553T>G p.S185A | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.027); catalogued as COSV99185181; called by muse, mutect2, varscan2
- JAKMIP1 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV51544656; called by muse, mutect2, varscan2
- JAKMIP2 | c.2412+1G>A p.X804_splice | Splice Site (SNP) | VAF 13/31 reads (42%) | catalogued as COSV99509464; called by muse, mutect2, varscan2
- LARP4 | c.700C>T p.H234Y | Missense Mutation (SNP) | VAF 378/615 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99529784; called by muse, mutect2, varscan2
- LRRC14 | c.554T>G p.L185R | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1257741961, COSV99468397; called by muse, mutect2, varscan2
- LRRK2 | c.7396C>A p.L2466I | Missense Mutation (SNP) | VAF 141/428 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.019); catalogued as COSV100111407; called by muse, mutect2, varscan2
- LTBP4 | c.168C>G p.C56W (on ENST00000308370 / NM_001042544.1; = p.A13G on NM_003573.2) | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.744); catalogued as COSV99199790; called by muse, mutect2, varscan2
- MAMDC4 | c.1504G>A p.G502S | Missense Mutation (SNP) | VAF 39/57 reads (68%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1427097155, COSV99915958; called by muse, mutect2, varscan2
- MTMR2 | c.28C>T p.L10F | Missense Mutation (SNP) | VAF 76/183 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.454); catalogued as COSV100656893; called by muse, mutect2
- MYOM2 | c.1411G>T p.V471F | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.043); catalogued as rs1200763875, COSV100038675; called by muse, mutect2, varscan2
- NIPAL4 | c.1380del p.V461Yfs*3 | Frame Shift Del (DEL) | VAF 12/30 reads (40%) | catalogued as rs1387475890; called by mutect2, pindel, varscan2
- NRK | c.4744G>A p.V1582I | Missense Mutation (SNP) | VAF 82/87 reads (94%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV99689424; called by muse, mutect2, varscan2
- OLFM3 | c.1216G>T p.V406F (on ENST00000338858 / NM_001288821.1; = p.V386F on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/109 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.431); catalogued as COSV100130252; called by muse, mutect2, varscan2
- PALB2 | c.1238C>G p.T413R | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs876660213, COSV99849127; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PIBF1 | c.13A>T p.I5F | Missense Mutation (SNP) | VAF 64/146 reads (44%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV100412058; called by muse, mutect2, varscan2
- PLPPR2 | c.91C>A p.L31M | Missense Mutation (SNP) | VAF 36/67 reads (54%) | SIFT tolerated (0.45); PolyPhen benign (0.062); catalogued as COSV99264186, COSV99264822; called by muse, mutect2, varscan2
- PSMB11 | c.337C>T p.R113W | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs376450654; called by muse, mutect2, varscan2
- RNGTT | c.454G>T p.A152S | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.941); catalogued as COSV99667671; called by muse, mutect2, varscan2
- RTL9 | c.941C>T p.S314F | Missense Mutation (SNP) | VAF 42/43 reads (98%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as COSV71825833; called by muse, mutect2, varscan2
- SALL2 | c.2230G>A p.G744R | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.805); catalogued as rs753233714, COSV100444113; called by muse, mutect2, varscan2
- SEMA3F | c.599A>T p.K200M | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99138123; called by muse, mutect2, varscan2
- SENP2 | c.1582G>T p.E528* | Nonsense Mutation (SNP) | VAF 17/50 reads (34%) | catalogued as COSV56198789, COSV99958360; called by muse, mutect2, varscan2
- SHANK3 | c.3338C>T p.A1113V | Missense Mutation (SNP) | VAF 38/57 reads (67%) | SIFT tolerated (0.17); PolyPhen benign (0.085); catalogued as rs752933975, COSV99438221; called by muse, mutect2, varscan2
- SLC26A6 | c.1957C>A p.P653T | Missense Mutation (SNP) | VAF 56/90 reads (62%) | SIFT tolerated (0.12); PolyPhen benign (0.142); catalogued as COSV100258849, COSV56574014, COSV56575993; called by muse, mutect2, varscan2
- SLC6A12 | c.809A>C p.Y270S | Missense Mutation (SNP) | VAF 118/207 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100675251; called by muse, mutect2, varscan2
- SMARCA4 | c.2291G>C p.W764S | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100759309; called by muse, mutect2, varscan2
- SMARCA4 | c.3484G>C p.G1162R | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100759311, COSV60788440, COSV60801054; called by muse, mutect2, varscan2
- TBP | c.356C>A p.P119Q | Missense Mutation (SNP) | VAF 47/96 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.518); catalogued as COSV100027594; called by muse, mutect2, varscan2
- TMEM186 | c.466T>C p.C156R | Missense Mutation (SNP) | VAF 50/81 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV99191195; called by muse, mutect2, varscan2
- TMPRSS4 | c.214C>A p.P72T | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as COSV101449439, COSV71110495; called by muse, mutect2, varscan2
- TMX4 | c.160G>T p.E54* | Nonsense Mutation (SNP) | VAF 46/128 reads (36%) | catalogued as COSV99851694; called by muse, mutect2, varscan2
- TPCN1 | c.365T>A p.L122H | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100137181; called by muse, mutect2, varscan2
- TRAF3IP2 | c.1700C>A p.P567H | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100389977; called by muse, mutect2, varscan2
- TRHDE | c.2267C>T p.A756V | Missense Mutation (SNP) | VAF 125/387 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.195); catalogued as COSV99673065; called by muse, mutect2, varscan2
- TRIM63 | c.271G>A p.G91S | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs1332404125, COSV100958212; called by muse, mutect2
- TRPV3 | c.347A>G p.K116R | Missense Mutation (SNP) | VAF 47/71 reads (66%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV56795955; called by muse, mutect2, varscan2
- TTC21B | c.1280T>G p.F427C | Missense Mutation (SNP) | VAF 129/300 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV99693058; called by muse, mutect2, varscan2
- UNC13A | c.1679C>T p.T560M | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53200305; called by muse, mutect2, varscan2
- UNC5B | c.1599G>T p.Q533H | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV100101485; called by muse, mutect2, varscan2
- WDR19 | c.277G>C p.D93H | Missense Mutation (SNP) | VAF 47/89 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV99976052; called by muse, mutect2, varscan2
- YTHDC2 | c.449G>C p.R150T | Missense Mutation (SNP) | VAF 77/148 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as COSV99364004; called by muse, mutect2, varscan2
- ZBTB12 | c.334A>C p.M112L | Missense Mutation (SNP) | VAF 36/61 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV100977062; called by muse, mutect2, varscan2
- ZBTB26 | c.67A>G p.M23V | Missense Mutation (SNP) | VAF 55/119 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1248327843, COSV101021177; called by muse, mutect2, varscan2
- ZC3H7B | c.211T>C p.S71P | Missense Mutation (SNP) | VAF 85/131 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100687898; called by muse, mutect2, varscan2
- ZNF236 | c.2260C>A p.L754I | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT tolerated (0.5); PolyPhen benign (0.292); catalogued as COSV99471478; called by muse, mutect2, varscan2
- ZNF318 | c.6143C>T p.S2048F | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.804); catalogued as rs868572073, COSV100546584; called by muse, mutect2, varscan2
- ZNF366 | c.1906G>A p.A636T | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs771818347, COSV100574576, COSV59216282; called by muse, mutect2, varscan2
- ACP2 | c.894dup p.V299Cfs*5 | Frame Shift Ins (INS) | VAF 21/59 reads (36%) | called by mutect2, pindel, varscan2
- ANKRD11 | c.144del p.K49Rfs*3 | Frame Shift Del (DEL) | VAF 22/84 reads (26%) | called by mutect2, pindel, varscan2
- ATAD2B | c.1359del p.L454* | Frame Shift Del (DEL) | VAF 82/207 reads (40%) | called by mutect2, pindel, varscan2
- CDC37L1 | c.809dup p.R271Kfs*56 | Frame Shift Ins (INS) | VAF 20/58 reads (34%) | called by pindel, varscan2
- DBF4 | c.504_505del p.K168Nfs*5 | Frame Shift Del (DEL) | VAF 119/243 reads (49%) | called by mutect2, pindel, varscan2
- DDX11 | c.451del p.V151Cfs*10 | Frame Shift Del (DEL) | VAF 78/263 reads (30%) | called by mutect2, varscan2
- EXOC4 | c.1039_1041del p.D347del | In Frame Del (DEL) | VAF 35/60 reads (58%) | called by mutect2, pindel, varscan2
- GDF2 | c.74T>C p.L25P | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HSD17B8 | c.694_694+1del | Frame Shift Del (DEL) | VAF 38/88 reads (43%) | called by mutect2, pindel, varscan2
- IL21R | c.297_300del p.D100Sfs*26 | Frame Shift Del (DEL) | VAF 45/87 reads (52%) | called by mutect2, pindel, varscan2
- MSH2 | c.1607dup p.N536Kfs*2 | Frame Shift Ins (INS) | VAF 135/330 reads (41%) | called by mutect2, pindel, varscan2
- MUC16 | c.42941dup p.T14315Nfs*40 | Frame Shift Ins (INS) | VAF 18/49 reads (37%) | called by mutect2, pindel, varscan2
- PLCD1 | c.33_34+4del p.X11_splice | Splice Site (DEL) | VAF 33/121 reads (27%) | called by mutect2, pindel, varscan2
- POLN | c.303_332del p.A102_S111del | In Frame Del (DEL) | VAF 14/43 reads (33%) | called by mutect2, pindel, varscan2
- PROM2 | c.767G>T p.G256V | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.989); called by muse, mutect2
- UQCRC2 | c.1239del p.Q414Sfs*12 | Frame Shift Del (DEL) | VAF 19/79 reads (24%) | called by mutect2, pindel, varscan2
- ACTL6B | c.162G>A p.L54= | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as COSV50514272; called by muse, mutect2, varscan2
- APPL2 | c.1536G>T p.V512= | Silent (SNP) | VAF 63/108 reads (58%) | catalogued as COSV99315217; called by muse, mutect2, varscan2
- ARFGEF2 | c.1116G>A p.K372= | Silent (SNP) | VAF 8/180 reads (4%) | called by muse, mutect2
- ATMIN | c.1044A>T p.V348= | Silent (SNP) | VAF 42/118 reads (36%) | catalogued as COSV100214809; called by muse, mutect2, varscan2
- BAZ2B | c.984A>T p.P328= | Silent (SNP) | VAF 31/55 reads (56%) | catalogued as COSV100601140; called by muse, mutect2, varscan2
- C12orf66 | c.150C>T p.S50= | Silent (SNP) | VAF 124/187 reads (66%) | catalogued as COSV100320944; called by muse, mutect2, varscan2
- CRACD | c.2631C>T p.D877= | Silent (SNP) | VAF 30/59 reads (51%) | catalogued as COSV99950185; called by muse, mutect2, varscan2
- DDX6 | c.609C>A p.T203= | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as COSV99870748; called by muse, mutect2, varscan2
- ORAI1 | c.84C>A p.R28= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as COSV100345524; called by muse, mutect2, varscan2
- PABPN1 | c.360A>G p.E120= | Silent (SNP) | VAF 31/80 reads (39%) | catalogued as COSV99391303; called by muse, varscan2
- PDPR | c.2634G>C p.G878= | Silent (SNP) | VAF 33/87 reads (38%) | catalogued as rs775038419, COSV99848997; called by muse, mutect2, varscan2
- RINL | c.1327C>A p.R443= (on ENST00000591812 / NM_001195833.2; = p.R329= on NM_198445.4) | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as COSV100531403; called by muse, mutect2, varscan2
- RMND5A | c.210T>C p.D70= | Silent (SNP) | VAF 193/811 reads (24%) | catalogued as rs767555168, COSV52155222; called by muse, mutect2, varscan2
- UBR5 | c.7857T>A p.P2619= | Silent (SNP) | VAF 35/86 reads (41%) | catalogued as COSV99642191, COSV99642678; called by muse, mutect2, varscan2
- MIR30D | n.22T>A | RNA (SNP) | VAF 27/50 reads (54%) | called by muse, mutect2, varscan2
